Somatic mutation profile of tumor specimen ALCH-B46E-TTP1-A (aliquot ALCH-B46E-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B46E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,266 days).
Specimen ALCH-B46E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3785a36-67f1-4b74-8d3f-6c53d7e5fde2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46E-NB1-A (Blood Derived Normal), aliquot ALCH-B46E-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6caf2d-6208-4394-850c-836c9c536e48

The open-access MAF lists 515 somatic variants for this specimen: 370 protein-altering or splice-affecting, 96 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 96, Nonsense Mutation 26, Intron 23, Frame Shift Del 13, Splice Site 9, 3'UTR 8, RNA 8, 5'UTR 6, Splice Region 5, 5'Flank 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.1198C>T p.L400F (on ENST00000297504 / NM_001282291.2; = p.L383F on NM_007188.5) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1263191948, COSV52508027; called by muse, mutect2, varscan2
- ABCC1 | c.1264del p.E422Rfs*22 | Frame Shift Del (DEL) | VAF 21/204 reads (10%) | catalogued as COSV60679308; called by mutect2, pindel, varscan2
- ABT1 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs782097640, COSV51293795; called by muse, mutect2
- ACSM2B | c.1098G>A p.T366= | Splice Region (SNP) | VAF 12/107 reads (11%) | catalogued as rs772046996, COSV61657196; called by muse, mutect2, varscan2
- ADAMTS3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs745415950; called by muse, mutect2
- AMACR | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs1396608667; called by muse, mutect2
- ANK3 | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99782218; called by muse, mutect2, varscan2
- APOB | c.7775C>A p.T2592N | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1322531458; called by muse, mutect2, varscan2
- ARHGEF40 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs753935139, COSV53878745; called by muse, mutect2, varscan2
- ARMC1 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52534381; called by muse, mutect2, varscan2
- ATG16L1 | c.1079G>T p.G360V (on ENST00000392017 / NM_030803.7; = p.G341V on NM_017974.4) | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1299082861; called by muse, mutect2, varscan2
- CCDC86 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs749893683; called by muse, mutect2, varscan2
- CD93 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV55665051; called by muse, varscan2
- CEACAM6 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.902); catalogued as rs1568726398, COSV52266583; called by muse, mutect2, varscan2
- CEP162 | c.3220A>G p.I1074V | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1157668025, COSV57621694; called by muse, mutect2, varscan2
- CFAP52 | c.834C>G p.S278R | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV55347826; called by muse, mutect2, varscan2
- CNTNAP4 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56695033; called by muse, mutect2
- CPB1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1271046935; called by muse, mutect2, varscan2
- CROCC2 | c.4916A>C p.Q1639P | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as rs1248422419; called by muse, mutect2, varscan2
- CSMD2 | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201582245, COSV53921495; called by muse, mutect2, varscan2
- CTAG2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV55994168; called by muse, mutect2, varscan2
- DBX2 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs1051730537, COSV60339007; called by muse, mutect2
- DCAF8L2 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV70551011; called by muse, mutect2, varscan2
- DEUP1 | c.65T>C p.M22T | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1477219751, COSV53211283; called by muse, varscan2
- DIP2C | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as rs1475915459; called by muse, mutect2, varscan2
- DNAJC6 | c.2578G>T p.V860L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1213395431; called by muse, mutect2
- DQX1 | c.1622C>A p.A541E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52045684; called by muse, mutect2
- DUSP22 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 44/587 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV60525617; called by muse, mutect2
- ERVMER34-1 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.503); catalogued as rs1560436861; called by muse, mutect2, varscan2
- EYS | c.1999C>A p.R667S | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV104424407; called by muse, mutect2
- FAM170B | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV104411702; called by muse, mutect2, varscan2
- FAM47B | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61456493; called by muse, mutect2, varscan2
- FASN | c.5248G>T p.E1750* | Nonsense Mutation (SNP) | VAF 37/473 reads (8%) | catalogued as COSV60753431; called by muse, mutect2
- FBLN1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 83/433 reads (19%) | catalogued as COSV53047324, COSV53054718; called by muse, mutect2, varscan2
- FGA | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57395592; called by muse, mutect2
- FLI1 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1355289095, COSV61379989; called by muse, mutect2, varscan2
- GAP43 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV59345019; called by muse, mutect2
- GDF6 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.326); catalogued as rs561421783, COSV99747956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GREB1L | c.3937C>A p.P1313T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs908503710; called by muse, mutect2
- GRM8 | c.2260G>T p.G754* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV58817152; called by muse, mutect2, varscan2
- GSG1L | c.710C>G p.T237R (on ENST00000447459 / NM_001109763.2; = p.T82R on NM_144675.2) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV104428481; called by muse, mutect2, varscan2
- GYS2 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53922543, COSV99679512; called by muse, mutect2, varscan2
- HCN1 | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV57491706, COSV57502530; called by muse, mutect2, varscan2
- HGFAC | c.1300G>T p.G434W | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66976616; called by muse, mutect2, varscan2
- HHAT | c.1307C>T p.T436I | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs952228974; called by muse, mutect2
- HMCN1 | c.7676A>G p.K2559R | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as rs1009060988; called by muse, mutect2, varscan2
- IGHE | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1318124445; called by muse, mutect2, varscan2
- IGKV1-6 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 106/623 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs752300089; called by muse, varscan2
- ING1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs201490185; called by muse, mutect2, varscan2
- IRAK4 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256576898; called by muse, mutect2
- ITM2A | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); catalogued as COSV64811908; called by muse, mutect2, varscan2
- JPH2 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs766721028; called by muse, mutect2, varscan2
- KIF4B | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70530189; called by muse, mutect2, varscan2
- LGALS9 | c.1057G>T p.V353L (on ENST00000395473 / NM_009587.3; = p.V321L on NM_002308.4) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV56348886; called by muse, mutect2
- LGR6 | c.426G>A p.S142= (on ENST00000367278 / NM_001017403.1; = p.S90= on NM_021636.3) | Splice Region (SNP) | VAF 63/318 reads (20%) | catalogued as rs1384325957; called by muse, mutect2, varscan2
- LRRC4C | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53427377; called by muse, mutect2
- LRRC4C | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53424202; called by muse, mutect2, varscan2
- LRRC7 | c.4250C>A p.T1417K (on ENST00000651989 / NM_001370785.2; = p.T1337K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs951900790; called by muse, mutect2, varscan2
- MACF1 | c.13988A>G p.Q4663R (on ENST00000372915; = p.Q2596R on NM_012090.5) | Missense Mutation (SNP) | VAF 63/371 reads (17%) | catalogued as rs1003379540; called by muse, mutect2, varscan2
- MGAM2 | c.2494C>A p.Q832K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.843); catalogued as rs1422265999; called by muse, mutect2
- MMP16 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54170667; called by muse, mutect2, varscan2
- MOAP1 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs773363613; called by muse, mutect2
- MS4A6A | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs772651842; called by muse, mutect2
- MTOR | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV63879169; called by muse, mutect2
- MUC5B | c.1006C>G p.Q336E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1266435179; called by muse, mutect2, varscan2
- MYLK2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779709086; called by muse, mutect2, varscan2
- N4BP1 | c.701A>C p.E234A | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1434249655; called by muse, mutect2, varscan2
- NCKAP5L | c.2959G>T p.A987S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1302694555; called by muse, mutect2
- NELL1 | c.1266C>A p.Y422* | Nonsense Mutation (SNP) | VAF 14/163 reads (9%) | catalogued as rs749878515; called by muse, mutect2
- NELL2 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61574444; called by muse, mutect2, varscan2
- NF1 | c.2851-1G>T p.X951_splice | Splice Site (SNP) | VAF 16/135 reads (12%) | catalogued as CD000081, CS1311517, COSV62220039; called by muse, mutect2, varscan2
- NLGN4X | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 107/609 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99324807; called by muse, mutect2, varscan2
- NOP2 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV58906160; called by muse, mutect2, varscan2
- NUTM1 | c.748C>G p.R250G | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100412374; called by muse, mutect2, varscan2
- OPRK1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572641, COSV55572689; called by muse, mutect2, varscan2
- OPRM1 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200954200; called by muse, mutect2, varscan2
- OR13C9 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99403462; called by muse, mutect2, varscan2
- OR13F1 | c.953T>A p.L318H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as rs201738627; called by muse, mutect2, varscan2
- OR52A1 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV61091891; called by muse, mutect2
- OR5F1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV53545793; called by muse, mutect2, varscan2
- OR8D4 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV58430824; called by mutect2, varscan2
- PDE3B | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV56385120; called by muse, mutect2
- PRKCB | c.1513C>A p.P505T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57775144; called by muse, mutect2, varscan2
- PRR33 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs952280626; called by muse, mutect2
- RABGAP1 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV100438579; called by muse, mutect2, varscan2
- REG1A | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52069806; called by muse, mutect2, varscan2
- RELN | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 41/272 reads (15%) | catalogued as COSV59018053; called by muse, mutect2, varscan2
- RYR1 | c.12523C>A p.P4175T | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100615810; called by muse, mutect2, varscan2
- SAMSN1 | c.161del p.G54Efs*17 | Frame Shift Del (DEL) | VAF 23/159 reads (14%) | catalogued as COSV53467776, COSV53468179; called by mutect2, pindel, varscan2
- SEC31B | c.2596G>T p.A866S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs771514333; called by muse, mutect2, varscan2
- SLC27A6 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.156); catalogued as rs371513145; called by muse, mutect2, varscan2
- SLC39A6 | c.1047G>T p.M349I | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.479); catalogued as COSV52370153; called by muse, varscan2
- SOGA3 | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1481899331; called by muse, mutect2
- SPAG17 | c.2653G>T p.E885* | Nonsense Mutation (SNP) | VAF 42/198 reads (21%) | catalogued as rs1262981740; called by muse, mutect2, varscan2
- SPTA1 | c.7053C>G p.I2351M | Missense Mutation (SNP) | VAF 57/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63757826; called by muse, mutect2, varscan2
- STK11 | c.460C>G p.H154D | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs878853988, CM123526, COSV58829856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYN3 | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60501499; called by muse, mutect2, varscan2
- TAOK3 | c.1063G>T p.V355L | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs61945174; called by muse, mutect2, varscan2
- TAS2R30 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs764262116; called by muse, mutect2
- TBX4 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 59/330 reads (18%) | catalogued as COSV99540680; called by muse, mutect2, varscan2
- TCN1 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV57253432; called by muse, mutect2
- TDRD5 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as rs779328331; called by muse, mutect2, varscan2
- THSD7B | c.3965G>T p.G1322V (on ENST00000272643; = p.G1320V on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778887956, COSV55675208, COSV99758514; called by muse, mutect2
- TLR1 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs753404339; called by muse, mutect2, varscan2
- TP53 | c.404del p.C135Sfs*35 | Frame Shift Del (DEL) | VAF 130/400 reads (33%) | catalogued as COSV52675774, COSV52680475, COSV52702460, COSV53452020; called by mutect2, pindel, varscan2
- TRPC5 | c.1837del p.L613Wfs*2 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | catalogued as COSV53300742; called by mutect2, pindel, varscan2
- TTN | c.5851G>A p.V1951I (on ENST00000591111; = p.V1905I on NM_003319.4) | Missense Mutation (SNP) | VAF 71/456 reads (16%) | PolyPhen benign (0); catalogued as rs765382880, COSV60198032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UROC1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 47/266 reads (18%) | catalogued as rs768125782; called by muse, mutect2, varscan2
- VWA3A | c.1532+1G>T p.X511_splice | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as rs754935116; called by muse, mutect2, varscan2
- VWF | c.4801C>G p.P1601A | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as CM088238; called by muse, mutect2
- WDFY2 | c.637del p.V213Cfs*45 | Frame Shift Del (DEL) | VAF 6/63 reads (10%) | catalogued as COSV99987074; called by mutect2, varscan2
- WDR24 | c.1030G>A p.D344N (on ENST00000248142; = p.D214N on NM_032259.4) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs1391260892, COSV104372903; called by muse, mutect2
- WT1 | c.1388-1G>T p.X463_splice | Splice Site (SNP) | VAF 28/416 reads (7%) | catalogued as CS075239; called by muse, mutect2
- XIRP2 | c.9311C>G p.S3104C (on ENST00000628543; = p.S3279C on NM_152381.6) | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV54685526; called by muse, mutect2, varscan2
- ZFHX4 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV51498082; called by muse, mutect2, varscan2
- ZNF100 | c.1510A>G p.K504E | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as rs763409906; called by muse, mutect2, varscan2
- ZNF423 | c.1422C>A p.N474K (on ENST00000563137 / NM_001379286.1; = p.N466K on NM_015069.4) | Missense Mutation (SNP) | VAF 39/377 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.078); catalogued as COSV52189641; called by muse, mutect2
- ZNF804A | c.1239G>C p.K413N | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV56464922; called by muse, mutect2, varscan2
- ABCC1 | c.2714G>T p.S905I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- ABCC11 | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACP6 | c.1052A>T p.K351I | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ACSM1 | c.1648-2A>G p.X550_splice | Splice Site (SNP) | VAF 19/155 reads (12%) | called by muse, mutect2, varscan2
- ADAM33 | c.2219G>C p.R740T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- ADAMTS14 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1009A>T p.S337C | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ADGB | c.3471G>T p.M1157I | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRA2A | c.1152_1153del p.K385Afs*89 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by pindel, varscan2
- AFF2 | c.3744C>A p.N1248K | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK9 | c.2319G>C p.E773D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.11717G>T p.R3906L (on ENST00000359028; = p.R3882L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL133500.1 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.87); called by muse, mutect2, varscan2
- ALOX12B | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 348/780 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPL | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- ANKRD24 | c.1879G>C p.A627P | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKRD65 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ARGFX | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.1958A>T p.H653L | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ASCC3 | c.4375G>T p.G1459W | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1A2 | c.1197C>A p.D399E | Missense Mutation (SNP) | VAF 125/431 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ATP2B4 | c.2467T>G p.F823V | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AVPR1A | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- BMP8A | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- BOD1L1 | c.6315G>T p.M2105I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf120 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C11orf96 | c.1298C>A p.S433* (on ENST00000339446; = p.S120* on NM_001145033.2) | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- C1QB | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- C1orf94 | c.1777G>T p.G593W (on ENST00000488417 / NM_001134734.2; = p.G403W on NM_032884.5) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C20orf173 | c.335C>A p.A112D (on ENST00000246199; = p.A165D on NM_001145350.2) | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- C6orf201 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 33/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- C8B | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CA3 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CALCA | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2
- CAPRIN2 | c.2450G>T p.R817L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CCDC171 | c.2801T>A p.V934E | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CCDC60 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by mutect2, varscan2
- CCKBR | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD99L2 | c.535+1G>T p.X179_splice | Splice Site (SNP) | VAF 45/297 reads (15%) | called by muse, mutect2, varscan2
- CEACAM21 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CEP290 | c.4807G>T p.A1603S | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP206 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CMYA5 | c.1925C>A p.S642Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- COL24A1 | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA3 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CUL4B | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2
- CUX1 | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CYP4B1 | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAXX | c.1847G>A p.G616D | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- DENND1A | c.453G>T p.V151= | Splice Region (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- DGAT2 | c.885G>C p.W295C | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DHX8 | c.1546+1G>T p.X516_splice | Splice Site (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- DISC1 | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 134/709 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DISC1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 132/709 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DNAH10 | c.6793G>C p.V2265L (on ENST00000409039; = p.V2204L on NM_207437.3) | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.8404C>A p.L2802I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.35); called by muse, mutect2
- DNHD1 | c.3235A>T p.I1079F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DPYSL5 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DRD5 | c.648C>G p.N216K | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DYNLRB2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2
- ECI1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 32/421 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF2AK4 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- EPHB4 | c.2065_2066del p.V689Hfs*69 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | called by mutect2, pindel, varscan2
- EVPLL | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- F13A1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT3 | c.9785G>T p.S3262I | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAT3 | c.10940A>C p.N3647T | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.117); called by muse, mutect2
- FBXO22 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FBXO5 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- FCGBP | c.2683G>C p.G895R | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLI1 | c.70G>T p.G24* | Nonsense Mutation (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- FLNB | c.3284G>T p.C1095F | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- FRMPD4 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FRMPD4 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- G6PD | c.770+1G>T p.X257_splice | Splice Site (SNP) | VAF 45/201 reads (22%) | called by muse, mutect2, varscan2
- GABRG3 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCNT7 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GJA3 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLRX5 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GPNMB | c.361A>T p.R121* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2
- GPR42 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- GPR65 | c.807C>A p.Y269* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- GRIN3B | c.1565C>A p.A522D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- GRK5 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GRPR | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GRPR | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- H3-5 | c.400A>T p.R134* | Nonsense Mutation (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2
- HADHA | c.1086-1G>T p.X362_splice | Splice Site (SNP) | VAF 48/324 reads (15%) | called by muse, mutect2, varscan2
- HCRT | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.033); called by muse, varscan2
- HDAC11 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEY1 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- HHLA2 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMCN1 | c.1855A>C p.K619Q | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HSPG2 | c.12816-3C>T | Splice Region (SNP) | VAF 71/451 reads (16%) | called by muse, mutect2, varscan2
- IFFO1 | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGFN1 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- IGLC7 | c.244C>A p.H82N | Missense Mutation (SNP) | VAF 62/696 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2
- IL18RAP | c.146del p.P49Qfs*46 | Frame Shift Del (DEL) | VAF 25/226 reads (11%) | called by mutect2, pindel, varscan2
- IL18RAP | c.1148G>T p.R383M | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INVS | c.2596A>T p.T866S | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQUB | c.2322G>T p.K774N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- JAKMIP3 | c.2338C>A p.R780S | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNV2 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIRREL1 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KLHL20 | c.754del p.Q252Rfs*20 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by mutect2, pindel, varscan2
- KRTAP8-1 | c.75T>A p.Y25* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- LCE2C | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LCOR | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDAH | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- LGSN | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LILRA1 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- LIPN | c.658_664del p.N220* | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | called by mutect2, pindel, varscan2
- LPAR4 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LTBP1 | c.4581G>A p.W1527* (on ENST00000404816 / NM_206943.4; = p.W1201* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2, varscan2
- MAP2K3 | c.693G>T p.M231I (on ENST00000342679 / NM_145109.3; = p.M202I on NM_002756.4) | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP7D2 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MBD3L3 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 40/664 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); called by muse, mutect2
- MILR1 | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 55/310 reads (18%) | called by muse, mutect2, varscan2
- MMRN1 | c.2042T>A p.L681Q | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- MN1 | c.1475C>A p.P492Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); called by muse, varscan2
- MOCS1 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL13 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MS4A8 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MSH5 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- MYO18B | c.6243G>T p.Q2081H | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- NAA11 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NAV3 | c.2031C>A p.D677E | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NCAPH | c.2104A>T p.M702L | Missense Mutation (SNP) | VAF 65/457 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCOA3 | c.3968C>T p.P1323L (on ENST00000371998 / NM_181659.3; = p.P1319L on NM_006534.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK10 | c.3376A>T p.I1126F | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NET1 | c.776G>T p.R259L (on ENST00000355029 / NM_001047160.3; = p.R205L on NM_005863.5) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NETO1 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); called by muse, mutect2
- NEUROG1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NID1 | c.2324C>A p.A775D | Missense Mutation (SNP) | VAF 35/351 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NID1 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NR1H4 | c.696G>T p.Q232H (on ENST00000551379 / NM_001206993.2; = p.Q218H on NM_005123.4) | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYAP2 | c.1690G>T p.G564C | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OBSCN | c.14119G>T p.A4707S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OLIG1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- OR10J3 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OR1L3 | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- OR2G6 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR52H1 | c.110A>G p.Y37C (on ENST00000322653; = p.Y43C on NM_001005289.1) | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR5B2 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR5M10 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5M8 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR9Q2 | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PAGE5 | c.377-1G>T p.X126_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- PANX1 | c.1223C>G p.T408S | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- PAPPA2 | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); called by muse, varscan2
- PAX1 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 44/266 reads (17%) | called by muse, mutect2, varscan2
- PDE3A | c.3121G>T p.E1041* | Nonsense Mutation (SNP) | VAF 27/376 reads (7%) | called by muse, mutect2
- PDGFRA | c.2002+8C>A | Splice Region (SNP) | VAF 50/280 reads (18%) | called by muse, varscan2
- PGBD1 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHF3 | c.5675G>T p.R1892M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF3 | c.5676G>T p.R1892S | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PIK3R6 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L1 | c.6483G>T p.Q2161H | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PLCXD3 | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- PLEKHM3 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU4F2 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R16B | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PPTC7 | c.572del p.P191Lfs*8 | Frame Shift Del (DEL) | VAF 24/264 reads (9%) | called by mutect2, pindel
- PRAME | c.1291A>T p.I431F | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); called by muse, mutect2
- PREX1 | c.4185G>T p.M1395I | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PSMB9 | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTCHD4 | c.1120T>A p.S374T | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTGIS | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPRC | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PTPRT | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PZP | c.3398G>T p.C1133F | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB3IP | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- RBMXL3 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RBP3 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- RC3H1 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- REEP3 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- RELN | c.6469C>A p.P2157T | Missense Mutation (SNP) | VAF 74/446 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RIMS1 | c.3425G>T p.R1142M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RIN3 | c.2417A>G p.N806S | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2
- RNF121 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- RNF40 | c.1721C>T p.T574I | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2
- RUBCNL | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SALL4 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 109/757 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCART1 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SCMH1 | c.1834C>A p.H612N (on ENST00000326197 / NM_001031694.2; = p.H543N on NM_012236.4) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCN2A | c.5212C>A p.P1738T | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SDK1 | c.5077G>C p.E1693Q | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC17A2 | c.141C>A p.N47K | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC35B4 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- SLC39A6 | c.1048A>T p.N350Y | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC4A10 | c.3119C>A p.P1040H (on ENST00000446997 / NM_001354461.2; = p.P1010H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLCO1B3 | c.1762C>A p.P588T | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMARCA5 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC1B | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- SOCS4 | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SOX11 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); called by muse, varscan2
- SPAG6 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2
- SPEF2 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2
- SPON1 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SPTAN1 | c.5200C>T p.Q1734* | Nonsense Mutation (SNP) | VAF 105/705 reads (15%) | called by muse, mutect2, varscan2
- SPTB | c.4937G>T p.R1646L | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SPTBN4 | c.4720G>T p.V1574L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>T p.R1724L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- SPTBN5 | c.5170C>G p.R1724G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); called by muse, mutect2
- SRCAP | c.6986G>T p.R2329L | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2
- STAB1 | c.4065G>T p.E1355D | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- STPG2 | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SUPT20HL2 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SYNDIG1L | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- SYT2 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAAR9 | c.283del p.E95Rfs*44 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- TAF1L | c.3724G>C p.E1242Q | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2
- TASOR2 | c.2516A>T p.E839V | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TBX18 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2
- TDRD6 | c.5539G>C p.E1847Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEX36 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 34/306 reads (11%) | called by muse, mutect2, varscan2
- TEX37 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, varscan2
- TG | c.2243A>C p.N748T | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2
- TGFBRAP1 | c.1246G>C p.G416R | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TGM6 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM132E | c.2868G>T p.W956C (on ENST00000321639; = p.W1046C on NM_001304438.2) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM250 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TMEM47 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TNN | c.1560C>A p.S520R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNNI2 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TNR | c.1789C>A p.P597T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TREML4 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM66 | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- TRPA1 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TRPM6 | c.4818C>G p.D1606E | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TSPOAP1 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TTN | c.49627C>A p.L16543I (on ENST00000591111; = p.L9119I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- UBE3A | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR5 | c.1710C>G p.D570E | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- USH2A | c.14141C>T p.A4714V | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- VCAN | c.2203del p.H735Mfs*9 | Frame Shift Del (DEL) | VAF 42/261 reads (16%) | called by mutect2, pindel, varscan2
- VGF | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- VPS13D | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- YY2 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ZGRF1 | c.2667G>T p.Q889H | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZNF300 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF492 | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF536 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF574 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ZNF578 | c.1582C>A p.R528S | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF717 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, varscan2
- ZNF90 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ZNF98 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZP1 | c.1335G>T p.R445S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZSWIM6 | c.1421G>T p.S474I | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ABCG1 | c.771G>T p.S257= | Silent (SNP) | VAF 72/215 reads (33%) | called by muse, mutect2, varscan2
- ACTL6B | c.828T>A p.A276= | Silent (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- ADA | c.411G>T p.L137= | Silent (SNP) | VAF 44/270 reads (16%) | catalogued as rs1392450389; called by muse, mutect2, varscan2
- ADGRA2 | c.795C>A p.P265= | Silent (SNP) | VAF 47/222 reads (21%) | called by muse, mutect2, varscan2
- ALOX15 | c.549C>A p.A183= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs147083325; called by muse, mutect2, varscan2
- AMER3 | c.2061A>T p.S687= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- ANK3 | c.864C>T p.L288= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs145971956; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKEF1 | c.972G>C p.L324= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- AOX1 | c.3765T>A p.P1255= | Silent (SNP) | VAF 65/444 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.7776C>A p.T2592= | Silent (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- ARSH | c.426G>T p.G142= | Silent (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- BBC3 | c.732C>T p.P244= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1247197811, COSV100340868; called by muse, mutect2, varscan2
- BCL11A | c.978C>A p.L326= (on ENST00000335712 / NM_001365609.1; = p.L360= on NM_018014.4) | Silent (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- BTN3A1 | c.1449T>C p.H483= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- C10orf71 | c.3102C>T p.H1034= | Silent (SNP) | VAF 38/283 reads (13%) | catalogued as rs762239726; called by muse, mutect2, varscan2
- C10orf90 | c.1128G>T p.V376= | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- C1orf159 | c.135C>T p.G45= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as rs1202454329; called by muse, mutect2
- CACNA1E | c.4824T>A p.P1608= | Silent (SNP) | VAF 48/265 reads (18%) | called by muse, mutect2, varscan2
- CAPN14 | c.186G>T p.L62= | Silent (SNP) | VAF 56/322 reads (17%) | called by mutect2, varscan2
- CASP12 | c.945C>A p.T315= | Silent (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- CCDC114 | c.1905G>A p.A635= | Silent (SNP) | VAF 52/294 reads (18%) | catalogued as rs762838065; called by muse, mutect2, varscan2
- CCDC168 | c.7395C>T p.D2465= | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- CDH9 | c.1158C>A p.V386= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV50555259; called by muse, mutect2, varscan2
- CFAP43 | c.114C>T p.N38= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs1165892970, COSV53382233; called by muse, mutect2, varscan2
- COL11A1 | c.3207C>G p.G1069= | Silent (SNP) | VAF 55/293 reads (19%) | called by muse, mutect2, varscan2
- COL12A1 | c.6585C>A p.P2195= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- COL6A3 | c.6015C>A p.P2005= | Silent (SNP) | VAF 64/343 reads (19%) | called by muse, mutect2, varscan2
- CXCL12 | c.66G>A p.K22= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1029C>G p.P343= | Silent (SNP) | VAF 19/196 reads (10%) | catalogued as COSV100758600; called by muse, mutect2
- DCHS1 | c.558G>T p.G186= | Silent (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- DEFB119 | c.216C>A p.T72= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- DIS3L2 | c.1464C>T p.S488= | Silent (SNP) | VAF 56/279 reads (20%) | called by muse, mutect2, varscan2
- DNAJC6 | c.2577G>T p.L859= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as COSV54772460; called by muse, mutect2
- DSP | c.3426G>T p.L1142= | Silent (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2, varscan2
- DSP | c.4704G>T p.L1568= | Silent (SNP) | VAF 41/236 reads (17%) | called by muse, mutect2, varscan2
- EBLN1 | c.651T>C p.P217= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- EFCAB12 | c.711G>A p.V237= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as rs927762233; called by muse, mutect2, varscan2
- FAM110A | c.780C>G p.A260= | Silent (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- FIBIN | c.219C>A p.G73= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- FOXL1 | c.570C>G p.P190= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- GLRA2 | c.321G>T p.L107= | Silent (SNP) | VAF 41/200 reads (21%) | called by muse, mutect2, varscan2
- GRIA2 | c.2424C>A p.L808= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- GRM8 | c.2076A>T p.P692= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- GTF3C5 | c.1119G>T p.S373= | Silent (SNP) | VAF 44/260 reads (17%) | called by muse, mutect2, varscan2
- HOXD13 | c.774C>A p.S258= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- KCNA6 | c.1266G>T p.T422= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs769793591; called by muse, mutect2, varscan2
- KCNC2 | c.396G>T p.P132= | Silent (SNP) | VAF 77/510 reads (15%) | catalogued as rs769487574; called by muse, mutect2, varscan2
- KIF26B | c.5181C>A p.A1727= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as COSV100831510; called by muse, mutect2, varscan2
- KIR2DL1 | c.762C>A p.I254= | Silent (SNP) | VAF 54/384 reads (14%) | catalogued as rs761782704; called by muse, mutect2, varscan2
- LACTBL1 | c.453G>T p.L151= (on ENST00000618559; = p.L196= on NM_001289974.2) | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- LMOD2 | c.855C>A p.I285= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs749656289, COSV71755833; called by muse, mutect2, varscan2
- LRFN5 | c.456G>T p.L152= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV53250050, COSV99985355; called by muse, mutect2, varscan2
- LRP1B | c.7665C>T p.G2555= | Silent (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- MTUS1 | c.2853G>A p.L951= (on ENST00000262102 / NM_001363061.1; = p.L117= on NM_020749.4) | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV99869776; called by muse, mutect2, varscan2
- NALCN | c.4618C>A p.R1540= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV51918025; called by muse, mutect2, varscan2
- NAV3 | c.483T>A p.A161= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as COSV57062553; called by muse, mutect2, varscan2
- NR4A3 | c.555C>A p.G185= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- OCA2 | c.1167C>T p.A389= | Silent (SNP) | VAF 202/614 reads (33%) | called by muse, mutect2, varscan2
- OR13C9 | c.867C>A p.P289= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as COSV99403492; called by muse, mutect2, varscan2
- OR2A12 | c.627G>A p.P209= | Silent (SNP) | VAF 78/384 reads (20%) | catalogued as rs767039928, COSV68821770; called by muse, mutect2, varscan2
- OR4C6 | c.81T>A p.A27= | Silent (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- OR56A1 | c.411C>T p.S137= | Silent (SNP) | VAF 28/308 reads (9%) | catalogued as rs1322665884; called by muse, mutect2
- OR56B1 | c.816G>C p.L272= | Silent (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- PAPPA2 | c.3072C>A p.T1024= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as rs1194709059; called by muse, mutect2, varscan2
- PARP3 | c.471A>G p.A157= | Silent (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.2928C>A p.A976= | Silent (SNP) | VAF 29/254 reads (11%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1593G>A p.L531= | Silent (SNP) | VAF 115/676 reads (17%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1176C>T p.R392= | Silent (SNP) | VAF 67/360 reads (19%) | catalogued as COSV65348024; called by muse, mutect2, varscan2
- PCK1 | c.195C>A p.I65= | Silent (SNP) | VAF 51/211 reads (24%) | called by muse, mutect2, varscan2
- PDLIM3 | c.204G>T p.R68= (on ENST00000284770 / NM_001257963.1; = p.R235= on NM_014476.6) | Silent (SNP) | VAF 55/334 reads (16%) | called by muse, mutect2, varscan2
- PHYHIPL | c.99C>T p.D33= | Silent (SNP) | VAF 40/292 reads (14%) | called by muse, mutect2, varscan2
- PLEKHA2 | c.414G>T p.L138= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as rs528896922; called by muse, mutect2, varscan2
- PRDM16 | c.1968G>T p.P656= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV54591706; called by mutect2, varscan2
- PRR33 | c.1107C>A p.P369= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1292832344; called by muse, mutect2
- RBM5 | c.1200A>T p.A400= | Silent (SNP) | VAF 39/232 reads (17%) | called by muse, mutect2, varscan2
- RGS9 | c.1839C>A p.P613= | Silent (SNP) | VAF 44/243 reads (18%) | catalogued as COSV99287235; called by muse, mutect2, varscan2
- SALL1 | c.2673G>T p.G891= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs149991313; called by muse, mutect2, varscan2
- SCN3A | c.5412G>T p.A1804= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as rs757643326, COSV51804401; called by muse, mutect2, varscan2
- SHISA9 | c.1161C>A p.G387= | Silent (SNP) | VAF 26/317 reads (8%) | called by muse, mutect2
- SLC2A9 | c.789G>A p.K263= | Silent (SNP) | VAF 73/474 reads (15%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1257C>A p.P419= | Silent (SNP) | VAF 36/264 reads (14%) | catalogued as COSV50907164; called by muse, mutect2, varscan2
- SLITRK3 | c.1641C>G p.V547= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- SOHLH1 | c.240G>A p.L80= | Silent (SNP) | VAF 96/531 reads (18%) | called by muse, mutect2, varscan2
- SPART | c.381A>T p.P127= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- STAB2 | c.3771G>A p.V1257= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.717C>G p.G239= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as rs181520520; called by muse, mutect2, varscan2
- TIAM1 | c.846G>T p.P282= | Silent (SNP) | VAF 42/296 reads (14%) | catalogued as COSV54550376; called by muse, mutect2, varscan2
- TKTL2 | c.81C>A p.S27= | Silent (SNP) | VAF 23/195 reads (12%) | called by muse, mutect2, varscan2
- TMEM74B | c.270T>G p.G90= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- TNXB | c.6864C>A p.T2288= (on ENST00000647633; = p.T2041= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/342 reads (16%) | catalogued as rs773758421, COSV64472853; called by muse, mutect2, varscan2
- TRERF1 | c.2556G>T p.L852= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- VPS13D | c.4026C>T p.L1342= | Silent (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- VWF | c.3918G>A p.R1306= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- WDFY4 | c.5298T>C p.G1766= | Silent (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- WDR75 | c.27G>T p.V9= | Silent (SNP) | VAF 70/464 reads (15%) | called by muse, mutect2, varscan2
- XKR7 | c.714G>A p.L238= | Silent (SNP) | VAF 51/261 reads (20%) | catalogued as rs1362819315; called by muse, mutect2, varscan2
- AC024940.1 | n.2404C>A | RNA (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148150 G>T | 5'Flank (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- AL132655.6 | chr20:58840736 C>G | 5'Flank (SNP) | VAF 90/341 reads (26%) | called by muse, mutect2, varscan2
- AMPD2 | c.91+997G>T | Intron (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- BMERB1 | chr16:15591036 del A | 3'Flank (DEL) | VAF 30/228 reads (13%) | called by mutect2, varscan2
- BOC | c.376+12C>G | Intron (SNP) | VAF 41/195 reads (21%) | called by muse, mutect2, varscan2
- CA4 | c.514-32G>A | Intron (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
- CCDC28B | c.548+21G>T | Intron (SNP) | VAF 14/114 reads (12%) | called by muse, varscan2
- CCL19 | c.*18G>A | 3'UTR (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- CFAP99 | chr4:2458802 T>C | 5'Flank (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*3107C>T | 3'UTR (SNP) | VAF 13/62 reads (21%) | catalogued as rs1413933690; called by muse, mutect2, varscan2
- CHRNA4 | c.*108C>A | 3'UTR (SNP) | VAF 70/528 reads (13%) | called by muse, mutect2, varscan2
- CRYBG1 | c.4846-373G>A | Intron (SNP) | VAF 23/132 reads (17%) | catalogued as rs920090594; called by muse, mutect2, varscan2
- DBN1 | c.956-427C>T | Intron (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- FOXP2 | c.1267-1539del | Intron (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel, varscan2
- GATA6 | c.*25G>T | 3'UTR (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.2144G>T | RNA (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- HTR3A | c.265-44G>A | Intron (SNP) | VAF 42/148 reads (28%) | called by muse, varscan2
- IGFN1 | c.1242-1301C>T | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as rs1344529510; called by muse, mutect2, varscan2
- IQGAP2 | c.*38G>T | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- LINC01169 | n.155G>T | RNA (SNP) | VAF 8/28 reads (29%) | catalogued as rs568632743; called by muse, mutect2, varscan2
- LINC01553 | n.1176G>T | RNA (SNP) | VAF 15/124 reads (12%) | catalogued as rs1197077341; called by muse, mutect2, varscan2
- MGAM | c.4619-12083C>A | Intron (SNP) | VAF 44/306 reads (14%) | catalogued as COSV72073730; called by muse, varscan2
- MMP7 | c.*32C>T | 3'UTR (SNP) | VAF 14/56 reads (25%) | catalogued as rs775546674; called by muse, mutect2, varscan2
- MS4A5 | c.492+1505del | Intron (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- NETO1 | c.29-337C>A | Intron (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
- NETO1 | c.29-338C>A | Intron (SNP) | VAF 30/196 reads (15%) | catalogued as COSV55018050; called by muse, mutect2, varscan2
- NUDT14 | c.126-233G>T | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- NUP35 | c.339+450G>A | Intron (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- OFCC1 | n.1754C>T | RNA (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- PAX6 | c.357+41del | Intron (DEL) | VAF 24/243 reads (10%) | called by mutect2, varscan2
- PDE6A | c.2200-45G>A | Intron (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- PHACTR1 | c.251-119548G>T | Intron (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2, varscan2
- POTEG | c.811-1107G>T | Intron (SNP) | VAF 20/428 reads (5%) | catalogued as rs1226840845; called by muse, mutect2
- RARS2 | c.111-391A>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- REL | c.-58G>T | 5'UTR (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- RGS4 | c.-42del | 5'UTR (DEL) | VAF 38/339 reads (11%) | called by mutect2, pindel, varscan2
- ROGDI | c.-13G>A | 5'UTR (SNP) | VAF 7/64 reads (11%) | catalogued as COSV58926792; called by muse, mutect2, varscan2
- SDC1 | c.*455G>T | 3'UTR (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99587309; called by muse, mutect2, varscan2
- SLC25A48 | c.679+90G>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV50848652; called by muse, mutect2, varscan2
- SSPOP | n.13499G>T | RNA (SNP) | VAF 24/180 reads (13%) | catalogued as COSV65130957; called by muse, mutect2, varscan2
- SSPOP | n.15011C>A | RNA (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- TBCK | c.597+693G>T | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- TCP10L3 | n.95G>C | RNA (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- TFF3 | c.-82A>T | 5'UTR (SNP) | VAF 72/185 reads (39%) | called by muse, mutect2, varscan2
- TGIF1 | c.-139G>T | 5'UTR (SNP) | VAF 31/119 reads (26%) | catalogued as rs757783979; called by muse, mutect2, varscan2
- TPD52L3 | c.*1148C>A | 3'UTR (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- VIP | c.468-17G>T | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- ZNF638 | c.-73G>T | 5'UTR (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
